TCGA case TCGA-2G-AAGK — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a1a4313c-9c5b-432c-a879-5425898ffaee

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 20 years; Year of birth: 1984; Vital status: Alive.

Diagnoses (2)
1. Mixed germ cell tumor (the primary disease): ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 20.2 years (7,378 days); Year of diagnosis: 2005; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,621 days (9.9 years); Ajcc serum tumor markers: S2.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 718 days (2.0 years); Days to treatment end: 774 days (2.1 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Mixed germ cell tumor), site: Intra-abdominal lymph nodes. Age at diagnosis: 22.2 years (8,091 days); Days to diagnosis: 713 days (2.0 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 713 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 713 days (2.0 years).
- Days to follow up: 3,290 days (9.0 years); Disease response: Tumor Free.
- Days to follow up: 3,621 days (9.9 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -3: Lactate Dehydrogenase 381; Alpha Fetoprotein 1198; Human Chorionic Gonadotropin 953.
- Day 38: Lactate Dehydrogenase 234; Human Chorionic Gonadotropin 5.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Testicular Cancer.
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAGK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 320 mg.
  Slide TCGA-2G-AAGK-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-2G-AAGK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAGK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor; Histologic diagnosis percent: 85.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 381; Pre orchi hcg: 953; Pre orchi afp: 1198.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 234; Post orchi hcg: 5.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers.
- Drug treatment 2: Pharmaceutical therapy drug name: Etoposid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,621 days; disease-specific survival: no event (censored), 3,621 days; disease-free interval: event (new tumor event after initially disease-free), 713 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 713 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAGK-01A-11D-A42X-01): tumor purity 0.58, ploidy 2.75, whole-genome doublings 1.
